Somatic mutation profile of tumor specimen 0DUVTR from CCDI case PBCLSM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.7 years (5,016 days).
Specimen 0DUVTR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42fd703b-a978-4a98-b77b-4301f5828c4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUVT4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/389f26d6-8c74-430f-8385-8e400cf279f3

The open-access MAF lists 69 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Intron 13, 3'UTR 9, Silent 7, 5'UTR 6, 5'Flank 2, 3'Flank 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 256/771 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALDH1A2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 150/483 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs778997757, COSV51092676; called by muse, mutect2, varscan2
- CCDC166 | c.797C>A p.A266E | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as rs1447514915; called by muse, mutect2
- CHTF18 | c.2923C>A p.L975I | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV50210821; called by muse, mutect2
- CSK | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328560214, COSV54976235; called by muse, mutect2, varscan2
- PANK2 | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1346198039; called by muse, mutect2
- PKD1L1 | c.3538C>G p.L1180V | Missense Mutation (SNP) | VAF 218/713 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs762446533; called by muse, mutect2, varscan2
- PROB1 | c.135C>A p.D45E | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.7); catalogued as COSV99042900; called by muse, mutect2
- PRR23B | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 161/572 reads (28%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as COSV61494452; called by muse, mutect2, varscan2
- RPRML | c.158C>A p.A53E | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as rs1471783897; called by muse, mutect2
- USP15 | c.1847G>A p.R616Q (on ENST00000280377 / NM_001351159.2; = p.R587Q on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/2398 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs775355642, COSV54796980; called by muse, mutect2
- ZNF407 | c.416C>A p.T139N | Missense Mutation (SNP) | VAF 17/445 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs1019585731; called by muse, mutect2
- ABHD17C | c.569C>A p.A190E | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP23 | c.3958C>A p.R1320S | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2
- BBOX1 | c.-38C>A | Splice Region (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- CACNA1F | c.1529G>C p.R510P | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CSK | c.391A>T p.I131F | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- GALNT5 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 107/659 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HS3ST3A1 | c.1084C>A p.H362N | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- IL10RA | c.1532C>A p.A511D | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); called by muse, mutect2
- MOB3A | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC5AC | c.6404C>T p.P2135L | Missense Mutation (SNP) | VAF 153/526 reads (29%) | SIFT tolerated (0.16); called by muse, mutect2, varscan2
- NKX2-6 | c.571C>A p.R191S | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- NTN5 | c.1019G>C p.S340T | Missense Mutation (SNP) | VAF 138/511 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTF1A | c.511C>A p.R171S | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC9A3R1 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 78/299 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ULK2 | c.2357C>A p.A786E | Missense Mutation (SNP) | VAF 24/653 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.134); called by muse, mutect2
- VPS37B | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 311/635 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS37C | c.735C>A p.Y245* | Nonsense Mutation (SNP) | VAF 115/344 reads (33%) | called by muse, mutect2, varscan2
- WNK1 | c.5120C>A p.T1707K (on ENST00000315939 / NM_018979.4; = p.T1460K on NM_014823.3) | Missense Mutation (SNP) | VAF 17/448 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); called by muse, mutect2
- ZSWIM8 | c.1856C>A p.A619D | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADRA2C | c.840C>A p.P280= | Silent (SNP) | VAF 7/160 reads (4%) | called by muse, mutect2
- IDNK | c.12G>C p.P4= | Silent (SNP) | VAF 41/231 reads (18%) | catalogued as rs1242597086; called by muse, mutect2, varscan2
- JMJD8 | c.16C>A p.R6= | Silent (SNP) | VAF 13/375 reads (3%) | called by muse, mutect2
- MYO15A | c.534C>T p.A178= | Silent (SNP) | VAF 138/532 reads (26%) | catalogued as rs749146534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OBSCN | c.20316C>T p.D6772= | Silent (SNP) | VAF 182/579 reads (31%) | called by muse, mutect2, varscan2
- PLXNB3 | c.258G>T p.V86= | Silent (SNP) | VAF 108/163 reads (66%) | called by muse, mutect2, varscan2
- TSC2 | c.415A>C p.R139= | Silent (SNP) | VAF 154/701 reads (22%) | catalogued as CD993486, COSV99553587; called by muse, mutect2, varscan2
- ATN1 | c.3540-78C>A | Intron (SNP) | VAF 5/43 reads (12%) | called by mutect2, varscan2
- C9orf50 | c.-36C>A | 5'UTR (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- DKK1 | c.243+59C>A | Intron (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- DNAJB12 | c.*18C>A | 3'UTR (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- EPCAM | c.76+100C>A | Intron (SNP) | VAF 4/44 reads (9%) | called by mutect2, varscan2
- EXPH5 | c.-118C>A | 5'UTR (SNP) | VAF 11/267 reads (4%) | catalogued as rs942507133; called by muse, mutect2
- FAM131B | c.91-42C>A | Intron (SNP) | VAF 11/191 reads (6%) | catalogued as rs1476687481; called by muse, mutect2
- FAM180A | c.-71C>A | 5'UTR (SNP) | VAF 4/44 reads (9%) | called by mutect2, varscan2
- FOXRED1 | c.*78C>A | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- GOLGB1 | c.*22C>A | 3'UTR (SNP) | VAF 14/308 reads (5%) | catalogued as COSV100100939; called by muse, mutect2
- IGFALS | c.-37C>T | 5'UTR (SNP) | VAF 59/204 reads (29%) | called by muse, mutect2, varscan2
- MFSD1 | chr3:158801999 C>A | 5'Flank (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- MYL6 | c.*12G>A | 3'UTR (SNP) | VAF 81/367 reads (22%) | called by muse, mutect2, varscan2
- NACAD | c.4258-47C>A | Intron (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- NEIL2 | c.*84C>A | 3'UTR (SNP) | VAF 5/78 reads (6%) | catalogued as COSV99462025; called by muse, mutect2
- PFKFB1 | chrX:54998496 G>T | 5'Flank (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- PIP5K1C | c.1920+1259C>A | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- PKMYT1 | c.873-80C>A | Intron (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- PTER | c.698+67C>A | Intron (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- RNASEK | c.-58C>A | 5'UTR (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- RNF212 | c.247-2536C>A | Intron (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- SERGEF | c.60+93C>A | Intron (SNP) | VAF 7/55 reads (13%) | called by muse, varscan2
- SLC11A1 | chr2:218398322 C>A | 3'Flank (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- SLC7A5 | c.1141-92C>A | Intron (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- SMIM35 | c.*1746G>T | 3'UTR (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- SYCE1L | c.*57C>A | 3'UTR (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- TRMT6 | c.-31C>A | 5'UTR (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- USP40 | c.2435-44C>A | Intron (SNP) | VAF 18/383 reads (5%) | called by muse, mutect2
- VWA1 | c.*74C>A | 3'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- WDR19 | c.406+63C>A | Intron (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- WNT1 | c.*84C>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
